Somatic mutation profile of tumor specimen TCGA-SX-A7SO-01A (aliquot TCGA-SX-A7SO-01A-11D-A34Z-10) from TCGA case TCGA-SX-A7SO, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 64.4 years (23,534 days).
Specimen TCGA-SX-A7SO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d2cb8471-f5bc-49e1-b8da-95a8537ee409.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SX-A7SO-10A (Blood Derived Normal), aliquot TCGA-SX-A7SO-10A-01D-A34Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a6761e1-fd3e-4236-baac-910638d59f1c

The open-access MAF lists 47 somatic variants for this specimen: 38 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 28, Silent 9, Nonsense Mutation 3, Frame Shift Del 3, Splice Region 1, Frame Shift Ins 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA7 | c.691A>C p.S231R | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99565195; called by muse, mutect2, varscan2
- ANPEP | c.215A>G p.N72S | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as COSV100262626; called by muse, mutect2, varscan2
- C3orf62 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 73/197 reads (37%) | catalogued as COSV100542921, COSV57985901; called by muse, mutect2, varscan2
- CELF2 | c.538T>A p.S180T (on ENST00000416382 / NM_001025077.3; = p.S187T on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/159 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as COSV100256780; called by muse, mutect2, varscan2
- COL9A1 | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 47/131 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753682260, COSV100294120, COSV57893257; called by muse, mutect2, varscan2
- EIF4G3 | c.3947T>G p.I1316S | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99943318; called by muse, mutect2, varscan2
- HEATR9 | c.1330C>A p.L444I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1404280943; called by muse, mutect2, varscan2
- HTR3A | c.1196G>C p.R399T | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.124); catalogued as rs755832055, COSV100248281; called by muse, mutect2, varscan2
- IGSF3 | c.423G>A p.V141= | Splice Region (SNP) | VAF 49/93 reads (53%) | catalogued as rs1220276607, COSV100604126; called by muse, mutect2, varscan2
- INHBE | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99875198; called by muse, mutect2, varscan2
- ITPR1 | c.4423T>A p.L1475M (on ENST00000354582; = p.L1460M on NM_002222.7) | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100229688; called by muse, mutect2, varscan2
- KRTAP4-3 | c.521G>A p.S174N | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as COSV101194141; called by muse, mutect2, varscan2
- LHX1 | c.1194del p.E399Kfs*2 | Frame Shift Del (DEL) | VAF 8/62 reads (13%) | catalogued as rs775423572; called by mutect2, pindel
- LRIT1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as rs776031813, COSV100928008; called by muse, varscan2
- NUDT13 | c.395A>G p.K132R | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.37); PolyPhen benign (0.011); catalogued as COSV100624680; called by muse, mutect2, varscan2
- OR8K3 | c.925A>T p.N309Y | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV100449669; called by muse, mutect2, varscan2
- PARP9 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs1335610903, COSV100830936, COSV100831044; called by muse, mutect2, varscan2
- PIDD1 | c.2513C>G p.S838C | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100204104, COSV100204222; called by muse, mutect2, varscan2
- PIK3R5 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs755332873, COSV99352920; called by muse, mutect2, varscan2
- PLA1A | c.1264G>C p.A422P | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.368); catalogued as COSV99845699; called by muse, mutect2, varscan2
- PLA2G6 | c.9C>A p.F3L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV100140228, COSV100140242; called by muse, mutect2, varscan2
- PLBD2 | c.1221G>A p.M407I | Missense Mutation (SNP) | VAF 33/89 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV99785200; called by muse, mutect2, varscan2
- RIPK4 | c.197T>C p.L66P | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100204663; called by muse, mutect2, varscan2
- RNF43 | c.88C>G p.L30V | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as COSV100089850; called by muse, mutect2, varscan2
- RYR2 | c.4547G>A p.G1516E | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100768182; called by muse, mutect2, varscan2
- SEZ6L2 | c.1811G>A p.R604H (on ENST00000308713 / NM_001114099.3; = p.R534H on NM_012410.4) | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as COSV100435118; called by muse, mutect2, varscan2
- SLC5A12 | c.169C>G p.L57V | Missense Mutation (SNP) | VAF 57/123 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99744447; called by muse, mutect2, varscan2
- STX18 | c.650C>G p.T217R | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.56); PolyPhen benign (0.049); catalogued as COSV100086034; called by muse, mutect2, varscan2
- SUGP1 | c.918C>A p.Y306* | Nonsense Mutation (SNP) | VAF 23/61 reads (38%) | catalogued as COSV99894661; called by muse, mutect2, varscan2
- TMC6 | c.1102G>T p.E368* | Nonsense Mutation (SNP) | VAF 11/24 reads (46%) | catalogued as COSV100129920; called by muse, mutect2, varscan2
- ZNF609 | c.2300G>C p.G767A | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.555); catalogued as rs1423205079, COSV100440408, COSV58591018; called by muse, mutect2, varscan2
- ZNF681 | c.5A>T p.E2V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.493); catalogued as COSV101267400, COSV68074636; called by muse, mutect2, varscan2
- CCDC7 | c.3314_3316del p.I1105del | In Frame Del (DEL) | VAF 72/194 reads (37%) | called by pindel, varscan2
- HGH1 | c.862A>G p.M288V | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- HMCN1 | c.7303_7312+3dup | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | called by mutect2, varscan2
- KNL1 | c.3638del p.P1213Lfs*5 (on ENST00000346991 / NM_170589.5; = p.P1187Lfs*5 on NM_144508.5) | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | called by mutect2, pindel, varscan2
- RNF24 | c.304_308+5del p.X102_splice | Splice Site (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- URI1 | c.1432del p.S478Lfs*5 | Frame Shift Del (DEL) | VAF 37/85 reads (44%) | called by mutect2, pindel, varscan2
- AC090517.4 | c.1326T>C p.V442= | Silent (SNP) | VAF 71/144 reads (49%) | catalogued as COSV99974116; called by muse, mutect2, varscan2
- AMIGO3 | c.213C>T p.N71= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs1221057060, COSV57537622; called by muse, mutect2, varscan2
- BCAR3 | c.969T>C p.D323= | Silent (SNP) | VAF 41/128 reads (32%) | catalogued as COSV99550292; called by muse, mutect2, varscan2
- CUL4A | c.984G>C p.R328= (on ENST00000375440 / NM_001008895.4; = p.R228= on NM_003589.3) | Silent (SNP) | VAF 39/90 reads (43%) | catalogued as COSV100417038; called by muse, mutect2, varscan2
- ERICH3 | c.63G>T p.L21= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as COSV100443468; called by muse, mutect2, varscan2
- OR51G2 | c.255A>T p.T85= | Silent (SNP) | VAF 30/64 reads (47%) | catalogued as COSV100432050; called by muse, mutect2, varscan2
- TMC2 | c.63G>A p.K21= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV100727362; called by muse, mutect2, varscan2
- ZNF266 | c.240T>A p.V80= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100749332; called by muse, mutect2, varscan2
- ZNF398 | c.285G>A p.K95= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100246815; called by muse, mutect2
